Gene-level copy-number profile of tumor specimen HTMCP-01-06-00634-01A from CGCI case HTMCP-01-06-00634, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen HTMCP-01-06-00634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 27f64ac5-7552-4b5c-b3c1-af85f93ef4bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00634-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/b7932197-58fa-4563-b9d8-f7bd54a1645e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,065; copy number 2: 47,405; copy number 3: 8,328; copy number 4: 7; copy number 5: 22; copy number 6: 15; copy number 7: 41; copy number 8: 13.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:80,233,664–80,247,683, 2 genes: AL513174.1, EIF5AP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 91 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:58,427,799–59,063,766, 1 gene, copy number 6 (within-gene range 4–6): LINC01122.
- chr2:59,014,354–62,350,739, 68 genes, copy number 6–8 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,378,804, 21 genes, copy number 5 (within-gene range 3–5): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.

Autosomal genes at a single copy (total copy number 1): 2,553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
